Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7858, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7858-01A (Primary Tumor).

Microscopic

Sections demonstrate gray and white matter which extensively infiltrated by a glioma, the cells of which resemble protoplasmic and fibrillary astrocytes. Microcystic change is focally striking. The cellularity is generally low and atypia mild. There are areas in which there is moderate hypercellularity and atypia ranges from generally moderate with a few highly atypical nuclei. A rare mitotic figure is seen and there is no microvascular proliferation nor necrosis.

Addendum

Scattered MIB-1 reactive cells are present with a calculated labeling index of 2.9%, indicative of a modestly proliferative neoplasm. The low level of proliferative activity argues against anaplastic progression of this tumor.

Diagnosis

Well differentiated astrocytoma Grade II

Source: NCI Genomic Data Commons file ed741aa5-28f6-430f-82ac-f8c79ae0e00c (TCGA-HT-7858.203F03EF-F7ED-46CE-9F5F-1C7A41B7FC4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).